Somatic mutation profile of tumor specimen ALCH-AE8H-TTP1-B (aliquot ALCH-AE8H-TTP1-B-1-0-D-A618-36) from ALCHEMIST case ALCH-AE8H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 80.5 years (29,409 days).
Specimen ALCH-AE8H-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ae90e57-8f81-4a81-bfff-411e2761ea58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE8H-NB1-A (Blood Derived Normal), aliquot ALCH-AE8H-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a86c8049-4d56-40c5-a8fc-7c5beb4b32ef

The open-access MAF lists 157 somatic variants for this specimen: 113 protein-altering or splice-affecting, 26 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 26, Nonsense Mutation 8, Intron 8, Splice Site 5, Splice Region 3, 3'UTR 3, 5'Flank 2, Frame Shift Del 2, 5'UTR 2, RNA 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.151-9_179del p.X51_splice | Splice Site (DEL) | VAF 12/144 reads (8%) | hotspot (GDC flag); called by mutect2, pindel
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 46/139 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD24 | c.978C>G p.I326M | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV53674129; called by muse, mutect2, varscan2
- ANKRD30A | c.553G>C p.E185Q (on ENST00000611781; = p.E129Q on NM_052997.2) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as COSV64617562; called by muse, mutect2, varscan2
- BACH1 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV54521100; called by muse, mutect2, varscan2
- CD207 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV101338578, COSV69652723; called by muse, mutect2, varscan2
- CDH9 | c.2140G>T p.D714Y | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1332556988, COSV50261146, COSV50291743; called by muse, varscan2
- CFTR | c.3409A>T p.M1137L | Missense Mutation (SNP) | VAF 48/429 reads (11%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.891); catalogued as CM931152; called by muse, mutect2, varscan2
- CILK1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63155794; called by muse, mutect2, varscan2
- CPEB4 | c.1774C>T p.R592* | Nonsense Mutation (SNP) | VAF 34/181 reads (19%) | catalogued as rs1412208413, COSV99436987; called by muse, mutect2, varscan2
- CYLD | c.1814C>G p.S605* | Nonsense Mutation (SNP) | VAF 33/208 reads (16%) | catalogued as COSV61095154; called by muse, varscan2
- DDX50 | c.825G>C p.Q275H | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101007283; called by muse, mutect2, varscan2
- DSCAM | c.1116G>T p.M372I | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT tolerated (1); PolyPhen probably damaging (0.968); catalogued as COSV68025420; called by muse, mutect2
- EOMES | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 32/150 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs1045041330, COSV55411844, COSV55412183; called by muse, mutect2, varscan2
- EPHA1 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369887921; called by muse, mutect2
- EYA1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 48/628 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); catalogued as rs561111097, CM136180, COSV58171414; called by muse, mutect2
- FAM111A | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 50/324 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs187051503; called by muse, mutect2, varscan2
- FMN2 | c.1244C>A p.T415N | Missense Mutation (SNP) | VAF 104/210 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs200347646; called by muse, mutect2, varscan2
- GLI3 | c.3635G>T p.G1212V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); catalogued as rs751373757, COSV67888535; called by mutect2, varscan2
- GOT1 | c.728A>G p.Y243C | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.176); catalogued as COSV65147696; called by muse, mutect2
- GPR39 | c.71A>C p.E24A | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61423493; called by muse, mutect2, varscan2
- HAS1 | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1329639804, COSV99708647; called by muse, mutect2, varscan2
- HELZ2 | c.7492G>T p.A2498S (on ENST00000467148 / NM_001037335.2; = p.A1929S on NM_033405.3) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV100918844; called by muse, mutect2, varscan2
- IQGAP2 | c.4081G>C p.E1361Q | Missense Mutation (SNP) | VAF 49/271 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as COSV99166890; called by muse, varscan2
- MGAM | c.5061G>C p.T1687= | Splice Region (SNP) | VAF 40/265 reads (15%) | catalogued as COSV72075161, COSV72075772; called by muse, mutect2, varscan2
- NCOA6 | c.129G>C p.L43F | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.36); catalogued as COSV62863279; called by muse, mutect2
- NECTIN3 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1194346576, COSV60551365; called by muse, mutect2, varscan2
- NEK5 | c.857C>G p.A286G | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV62879217; called by muse, mutect2, varscan2
- NOX5 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1228438558, COSV52997606; called by muse, mutect2
- OLFM2 | c.582C>T p.G194= | Splice Region (SNP) | VAF 9/47 reads (19%) | catalogued as rs1170451006; called by muse, mutect2, varscan2
- OR52L1 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs769350807, COSV59988162; called by muse, mutect2, varscan2
- PLEKHH2 | c.3629C>G p.T1210S | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as rs1473790982; called by muse, mutect2, varscan2
- RELN | c.474-1G>C p.X158_splice | Splice Site (SNP) | VAF 38/299 reads (13%) | catalogued as COSV100633997; called by muse, mutect2, varscan2
- ROBO3 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0.036); catalogued as COSV101184870; called by muse, mutect2, varscan2
- SLC26A5 | c.1894T>C p.F632L | Missense Mutation (SNP) | VAF 43/280 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs766693130; called by muse, mutect2, varscan2
- SORL1 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.023); catalogued as rs369018073; called by muse, mutect2, varscan2
- SPRY3 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 57/437 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as rs1236014606; called by muse, mutect2, varscan2
- STOML3 | c.191G>A p.R64H | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142178847; called by muse, mutect2, varscan2
- TIMELESS | c.3419C>T p.A1140V | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.076); catalogued as rs1420955034, COSV57514397; called by muse, mutect2, varscan2
- TMEM163 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as COSV56109656, COSV99029704; called by muse, mutect2, varscan2
- TMEM202 | c.656C>A p.S219* | Nonsense Mutation (SNP) | VAF 41/301 reads (14%) | catalogued as rs143780703, COSV58981921; called by muse, mutect2, varscan2
- TMEM30B | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs748338783; called by muse, mutect2, varscan2
- VPS13C | c.917A>G p.Y306C (on ENST00000644861 / NM_020821.3; = p.Y263C on NM_017684.5) | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs199504742; called by muse, mutect2, varscan2
- ZNF45 | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.665); catalogued as COSV99079325; called by muse, varscan2
- ZNF667 | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as COSV52640610; called by muse, mutect2
- ZNF835 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773193662; called by muse, mutect2, varscan2
- ADAM32 | c.1630T>A p.W544R | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- ADGRE5 | c.949G>T p.A317S (on ENST00000242786 / NM_078481.4; = p.A224S on NM_001784.5) | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALG13 | c.3082A>G p.T1028A | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ALMS1 | c.922T>C p.S308P | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATXN2 | c.2244T>G p.D748E (on ENST00000550104; = p.D588E on NM_002973.4) | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C1orf116 | c.282G>A p.R94= | Splice Region (SNP) | VAF 8/42 reads (19%) | called by muse, varscan2
- CCDC197 | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CD101 | c.1211A>T p.H404L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- CEL | c.912G>A p.M304I (on ENST00000673714; = p.M301I on NM_001807.6) | Missense Mutation (SNP) | VAF 98/662 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.001); called by muse, varscan2
- CFAP74 | c.2978G>C p.R993T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CILK1 | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- COL26A1 | c.376T>A p.C126S (on ENST00000313669 / NM_001278563.3; = p.C124S on NM_133457.4) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL6A3 | c.6753+2T>G p.X2251_splice | Splice Site (SNP) | VAF 45/265 reads (17%) | called by muse, mutect2, varscan2
- CTNNA3 | c.1473T>A p.H491Q | Missense Mutation (SNP) | VAF 25/195 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- DSCAM | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 23/250 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, mutect2
- DYRK4 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, varscan2
- EPCAM | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 37/234 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GIMD1 | c.637_654del p.V213_*218delext*43 | Nonstop Mutation (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- GOLGA8S | c.1041G>T p.Q347H | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, varscan2
- GRIK1 | c.2421T>A p.H807Q | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- GRK4 | c.238C>A p.H80N (on ENST00000398052 / NM_182982.3; = p.H48N on NM_005307.3) | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- HMGCR | c.722T>A p.V241D | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- HOXD3 | c.212A>G p.Q71R | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- HPGD | c.660G>C p.L220F | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- IL3RA | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 41/416 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2
- KIF3B | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- LAMA5 | c.7589A>G p.Q2530R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, varscan2
- LAP3 | c.1315A>G p.T439A | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- LILRB3 | c.20C>A p.A7D | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- LSM11 | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MARVELD2 | c.248del p.P83Lfs*80 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- MS4A13 | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEAL2 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NCK1 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 30/170 reads (18%) | called by muse, mutect2, varscan2
- NIPAL3 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.84); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- NIPAL3 | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- NLRX1 | c.656G>T p.R219L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- NMD3 | c.35C>G p.P12R | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NNT | c.340C>G p.Q114E | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NWD2 | c.3271C>T p.P1091S | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- OLFM3 | c.488A>G p.Y163C (on ENST00000338858 / NM_001288821.1; = p.Y143C on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR14A2 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- OTUD4 | c.1238G>T p.R413L (on ENST00000447906 / NM_001366057.1; = p.R348L on NM_001102653.1) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PABPC5 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- PCF11 | c.3401dup p.Y1135Ifs*2 | Frame Shift Ins (INS) | VAF 25/208 reads (12%) | called by mutect2, pindel, varscan2
- PCSK6 | c.2238_2241del p.R747Gfs*30 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | called by mutect2, pindel, varscan2
- PLEKHG5 | c.2645A>T p.E882V (on ENST00000400915 / NM_001042663.3; = p.E845V on NM_020631.6) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PLSCR5 | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 114/510 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPFIBP1 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RENBP | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- RGS6 | c.1297A>C p.M433L | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RIC8B | c.1065+1G>A p.X355_splice | Splice Site (SNP) | VAF 12/74 reads (16%) | called by muse, varscan2
- ROBO1 | c.2833C>G p.P945A | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2
- RPS6KC1 | c.2978A>T p.E993V | Missense Mutation (SNP) | VAF 65/467 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SBK2 | c.826G>T p.D276Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SEC22A | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- SETD2 | c.7533_7533+34del p.X2511_splice | Splice Site (DEL) | VAF 34/158 reads (22%) | called by mutect2, pindel
- SPA17 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPP2 | c.959A>T p.H320L | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TTC34 | c.2801G>T p.G934V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TTC4 | c.166A>T p.R56W | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ULK4 | c.2651T>C p.V884A | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- WDR19 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WWP1 | c.1575A>T p.K525N | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2
- WWP1 | c.2071C>T p.L691F | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, varscan2
- ZFHX3 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ZNF574 | c.157G>T p.G53* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
- CHAMP1 | c.867T>G p.P289= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- CPA1 | c.744T>C p.C248= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- CSMD2 | c.6177C>T p.H2059= | Silent (SNP) | VAF 19/354 reads (5%) | called by muse, mutect2
- DNAJC6 | c.331C>T p.L111= | Silent (SNP) | VAF 10/203 reads (5%) | called by muse, mutect2
- FLI1 | c.243G>A p.V81= | Silent (SNP) | VAF 9/51 reads (18%) | called by muse, varscan2
- GPR61 | c.1104G>A p.L368= | Silent (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- GRIA1 | c.2185C>A p.R729= | Silent (SNP) | VAF 30/203 reads (15%) | catalogued as rs775474938, COSV99599575; called by muse, mutect2, varscan2
- IRAK4 | c.955C>T p.L319= | Silent (SNP) | VAF 32/216 reads (15%) | catalogued as COSV71210914; called by muse, mutect2, varscan2
- LILRB3 | c.21C>A p.A7= | Silent (SNP) | VAF 22/332 reads (7%) | called by muse, mutect2
- LRRIQ1 | c.4590A>G p.R1530= | Silent (SNP) | VAF 53/374 reads (14%) | called by muse, varscan2
- MAPT | c.1377C>T p.D459= (on ENST00000262410 / NM_001377265.1; = p.D133= on NM_005910.5) | Silent (SNP) | VAF 89/390 reads (23%) | catalogued as rs371173110; ClinVar: likely benign; called by muse, mutect2, varscan2
- NADSYN1 | c.1095C>T p.T365= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as rs547742463, COSV59810868; called by muse, mutect2, varscan2
- PAPPA | c.2664G>T p.V888= | Silent (SNP) | VAF 66/213 reads (31%) | called by muse, mutect2, varscan2
- PELI3 | c.906G>T p.L302= | Silent (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- PIK3R5 | c.2211C>T p.A737= | Silent (SNP) | VAF 17/99 reads (17%) | called by muse, mutect2, varscan2
- PRR12 | c.165G>T p.P55= (on ENST00000615927; = p.P876= on NM_020719.3) | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.2706G>T p.T902= | Silent (SNP) | VAF 40/191 reads (21%) | catalogued as COSV101099785; called by muse, mutect2, varscan2
- SEL1L3 | c.1200C>T p.F400= | Silent (SNP) | VAF 13/289 reads (4%) | called by muse, mutect2
- SEMA4C | c.210A>G p.R70= | Silent (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2
- STARD5 | c.555A>G p.P185= | Silent (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- TACC1 | c.1794C>T p.L598= | Silent (SNP) | VAF 39/260 reads (15%) | called by muse, mutect2, varscan2
- TEX47 | c.265C>T p.L89= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as COSV99787169; called by muse, mutect2, varscan2
- TMEM132C | c.430C>A p.R144= | Silent (SNP) | VAF 60/301 reads (20%) | catalogued as rs769440363, COSV101473689, COSV70661123; called by muse, mutect2, varscan2
- WNK1 | c.732C>G p.T244= | Silent (SNP) | VAF 53/435 reads (12%) | called by muse, mutect2, varscan2
- ZBTB21 | c.969T>G p.G323= | Silent (SNP) | VAF 27/178 reads (15%) | catalogued as rs758526534; called by muse, mutect2, varscan2
- ZEB2 | c.213C>A p.S71= | Silent (SNP) | VAF 30/280 reads (11%) | called by muse, mutect2, varscan2
- AC024940.1 | n.24C>G | RNA (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- ALOX12B | c.755-39del | Intron (DEL) | VAF 26/100 reads (26%) | catalogued as COSV100047451; called by mutect2, pindel, varscan2
- APLN | c.*79C>T | 3'UTR (SNP) | VAF 74/207 reads (36%) | called by muse, mutect2, varscan2
- BCAP31 | c.-44-257C>G | Intron (SNP) | VAF 25/53 reads (47%) | catalogued as rs782375102, COSV54386922; called by muse, mutect2, varscan2
- BCKDK | c.*161C>T | 3'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- CASP12 | c.260-397T>A | Intron (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2, varscan2
- CCDC25 | c.76+773C>G | Intron (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- CYS1 | chr2:10083803 G>A | 5'Flank (SNP) | VAF 24/120 reads (20%) | called by muse, varscan2
- DDX39B | c.-2-588C>T | Intron (SNP) | VAF 41/170 reads (24%) | catalogued as rs1232772517; called by muse, mutect2, varscan2
- FLRT2 | chr14:85528851 A>G | 5'Flank (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- IGFLR1 | c.-21C>T | 5'UTR (SNP) | VAF 13/62 reads (21%) | catalogued as rs565456016; called by muse, mutect2, varscan2
- MSS51 | c.-13C>G | 5'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- PDS5A | c.3340-18C>T | Intron (SNP) | VAF 7/45 reads (16%) | catalogued as rs1231574734; called by muse, varscan2
- PON3 | c.777+30C>G | Intron (SNP) | VAF 47/310 reads (15%) | called by muse, mutect2, varscan2
- RNF170 | c.*2026A>G | 3'UTR (SNP) | VAF 30/506 reads (6%) | called by muse, mutect2
- UBBP4 | n.598G>T | RNA (SNP) | VAF 68/286 reads (24%) | called by muse, mutect2, varscan2
- USP10 | c.22-875G>C | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as rs1443072640; called by muse, mutect2, varscan2
- ZSWIM4 | chr19:13836406 G>A | 3'Flank (SNP) | VAF 12/76 reads (16%) | called by muse, varscan2
